Somatic mutation profile of tumor specimen TCGA-HT-7693-01A (aliquot TCGA-HT-7693-01A-11D-2253-08) from TCGA case TCGA-HT-7693, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 51.9 years (18,956 days).
Specimen TCGA-HT-7693-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55488053-ca4f-4287-8139-532885f71b9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7693-10A (Blood Derived Normal), aliquot TCGA-HT-7693-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efcea524-6d0b-42c3-9f21-6534a9be502d

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 10, Splice Site 1, Splice Region 1, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 51/106 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 32/34 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 86/202 reads (43%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.966); catalogued as rs369100046, COSV54004968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG13 | c.831G>C p.E277D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV52644250; called by muse, varscan2
- ATRX | c.6563G>A p.R2188Q | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64879508, COSV64879971; called by muse, mutect2, varscan2
- CELSR1 | c.5557G>A p.V1853I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs370579193; called by muse, mutect2, varscan2
- EPHA3 | c.2266A>G p.S756G | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV60723994; called by muse, mutect2, varscan2
- ERICH5 | c.672G>C p.E224D | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.606); catalogued as COSV59316957; called by muse, mutect2, varscan2
- F8 | c.2849A>G p.E950G | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV64277689, COSV64277945; called by muse, mutect2
- FAM76B | c.651G>C p.K217N | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as rs1451982157, COSV62557074; called by muse, mutect2, varscan2
- FYCO1 | c.56-2A>G p.X19_splice | Splice Site (SNP) | VAF 35/75 reads (47%) | catalogued as COSV56118995; called by muse, mutect2, varscan2
- HDX | c.877T>C p.C293R | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV52982165; called by muse, mutect2
- HECTD1 | c.5141G>A p.R1714H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs370774239; called by muse, mutect2, varscan2
- LRP2 | c.11456G>T p.G3819V | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55570684; called by muse, mutect2, varscan2
- MGAT4C | c.1234G>C p.D412H | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV59837117; called by muse, mutect2
- MMGT1 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.043); catalogued as rs150859420, COSV60003368; called by muse, mutect2, varscan2
- NOS2 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 12/265 reads (5%) | catalogued as COSV58226985; called by muse, mutect2
- OR5C1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1247902574, COSV65456649; called by muse, mutect2
- PAGE1 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1557142183, COSV65998735; called by muse, mutect2, varscan2
- PNN | c.706A>G p.K236E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.662); catalogued as COSV53768243; called by muse, mutect2, varscan2
- SLCO4C1 | c.69G>C p.L23F | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1489756327, COSV60519561; called by muse, mutect2, varscan2
- TAF1 | c.3611G>A p.R1204Q (on ENST00000373790 / NM_138923.4; = p.R1225Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as COSV52123409; called by muse, mutect2, varscan2
- TP53BP1 | c.5575A>G p.I1859V | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV53021045; called by muse, mutect2
- TRIM41 | c.436A>T p.R146W | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59322076; called by muse, mutect2, varscan2
- TSR2 | c.435G>C p.E145D | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.551); catalogued as COSV64309513; called by muse, mutect2, varscan2
- ZFAT | c.447A>G p.A149= | Splice Region (SNP) | VAF 96/227 reads (42%) | catalogued as COSV64745352; called by muse, mutect2, varscan2
- FRMPD3 | c.2544del p.F849Sfs*76 | Frame Shift Del (DEL) | VAF 11/102 reads (11%) | called by mutect2, pindel, varscan2
- CD248 | c.390C>T p.R130= | Silent (SNP) | VAF 34/53 reads (64%) | catalogued as rs574387936, COSV60937676; called by muse, mutect2, varscan2
- COLEC11 | c.747C>T p.G249= | Silent (SNP) | VAF 54/127 reads (43%) | catalogued as rs756469756, COSV52594164; called by muse, mutect2, varscan2
- ELOA2 | c.345C>T p.N115= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV55306395; called by muse, mutect2, varscan2
- KRTAP13-3 | c.45C>T p.H15= | Silent (SNP) | VAF 74/170 reads (44%) | catalogued as rs761771197, COSV61880153; called by muse, mutect2, varscan2
- MUC17 | c.10167A>T p.I3389= | Silent (SNP) | VAF 512/962 reads (53%) | catalogued as COSV100075330, COSV60299726; called by muse, varscan2
- NLRP5 | c.1542C>T p.G514= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs779756665, COSV66767046; called by muse, mutect2, varscan2
- PIEZO2 | c.6873T>G p.V2291= | Silent (SNP) | VAF 4/88 reads (5%) | catalogued as COSV53293337; called by muse, mutect2
- SELE | c.645G>T p.L215= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as COSV60977462; called by muse, mutect2
- SOGA1 | c.1102C>T p.L368= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV52913691; called by muse, mutect2, varscan2
- SULT1E1 | c.756G>A p.S252= | Silent (SNP) | VAF 72/229 reads (31%) | catalogued as rs376968582; called by muse, mutect2, varscan2
- SNORD116-26 | n.6G>A | RNA (SNP) | VAF 21/62 reads (34%) | catalogued as rs757729912; called by muse, mutect2, varscan2
